HCMI case HCM-BROD-0482-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c996d442-45aa-47e8-9a9c-82727085d22d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1962; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 54.5 years (19,904 days); Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2 days; Days to treatment end: 110 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 720 days (2.0 years); Days to treatment end: 964 days (2.6 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Non-small cell carcinoma: ICD-O-3 morphology code: 8046/6; ICD-10 code: C79.3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: metastasis; Age at diagnosis: 56.4 years (20,618 days); Days to diagnosis: 714 days (2.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin + Nivolumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 1 day; Days to treatment end: 714 days (2.0 years).
3. Squamous cell carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8070/6; ICD-10 code: C78.0; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 56.4 years (20,618 days); Days to diagnosis: 714 days (2.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Carboplatin + Etoposide; Treatment intent type: Maintenance Therapy; Days to treatment start: 1 day; Days to treatment end: 799 days (2.2 years); Treatment outcome: Stable Disease.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 985.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- EGFR: Negative.
- MET: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 54 kg; BMI: 23.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0482-C34-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0482-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
